Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A73F, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A73F-01A (Primary Tumor).

ICD-0-3
Carcinoma, hepatocellular NOS
8170/3
Site Livers C22.0
JW 8/11/13

Surgical Pathology

Requested By:

SLIDE DISPOSITION:

DIAGNOSIS:

A. Lymph node, omental, biopsy: Unremarkable fibroadipose tissue.

B. Liver, right lobe segment 6, wedge resection:

Well-differentiated hepatocellular carcinoma forming a solitary 6.5 x 5.0 x 3.0 cm mass. Vascular invasion is not identified. The surgical resection margins are free by 0.6 cm. The background liver does not show cirrhosis.

With available surgical material, [AJCC pT1] (7th edition, 2010).

This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

Interpreted by:

Report electronically signed by

Transcribed by:

GROSS DESCRIPTION:

A. Received fresh labeled "omental lymph node" is a 0.7 x 0.3 x 0.3 cm fibrofatty lymph node. All submitted. Grossed by

B. Received fresh labeled "liver right lobe portion segment 6" is a 152.4 gram, 10.5 x 7.0 x 3.0 cm liver wedge specimen. A single 6.5 x 5.0 x 3.0 cm red-tan heterogenous mass is present 0.6 cm from the surgical margin. Margin is submitted perpendicularly. Representative sections are submitted. Grossed by .

BLOCK SUMMARY:

Part A: Omental lymph node

1 Omentum LN 1 (A1)

Part B: Liver right lobe portion segment 6

- 1 Tumor 1
- 2 Tumor 1
- 3 Tumor 2
- 4 Tumor 2
- 5 Normal liver
- 6 Normal liver

IHPAA Discrepancy		

Source: NCI Genomic Data Commons file df7cf23d-6c3d-43bf-82e8-e75f8e42a3ca (TCGA-DD-A73F.2FCC867C-91AD-40B3-8046-FFB84BDD2EA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).